Somatic mutation profile of tumor specimen TCGA-56-A62T-01A (aliquot TCGA-56-A62T-01A-11D-A401-08) from TCGA case TCGA-56-A62T, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.1 years (28,522 days).
Specimen TCGA-56-A62T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb846c40-1b23-40f0-95c1-cc15572176c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-A62T-10A (Blood Derived Normal), aliquot TCGA-56-A62T-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8023fd59-7fe1-49d7-ae35-9c2a98602127

The open-access MAF lists 549 somatic variants for this specimen: 426 protein-altering or splice-affecting, 112 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 362, Silent 112, Nonsense Mutation 32, Splice Site 14, Frame Shift Del 11, RNA 4, Intron 3, Splice Region 3, Frame Shift Ins 3, 3'UTR 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.841); catalogued as COSV100741642, COSV100741808; called by muse, mutect2, varscan2
- ABCA12 | c.6322T>A p.F2108I (on ENST00000272895 / NM_173076.3; = p.F1790I on NM_015657.3) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55958390, COSV99790447; called by muse, mutect2
- ABCA12 | c.2684-1G>T p.X895_splice (on ENST00000272895 / NM_173076.3; = p.X577_splice on NM_015657.3) | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as rs1349342875, COSV55974149; called by muse, mutect2
- ABCA6 | c.2848G>A p.A950T | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99446758; called by muse, mutect2, varscan2
- ABCC3 | c.3371T>C p.L1124S | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as rs1424532321, COSV99559329; called by muse, mutect2, varscan2
- ABCC9 | c.2020-1G>T p.X674_splice | Splice Site (SNP) | VAF 31/50 reads (62%) | catalogued as COSV53967147, COSV99686027; called by muse, mutect2, varscan2
- ACAP1 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs143045247; called by muse, mutect2, varscan2
- ADAM21 | c.1420C>A p.P474T | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99961123; called by muse, mutect2, varscan2
- ADAMTS20 | c.1622G>T p.R541L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV67134638, COSV67137162; called by muse, mutect2, varscan2
- ADAMTS5 | c.1127G>A p.C376Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99537819; called by muse, mutect2, varscan2
- ADAMTS7 | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 71/128 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1425119722, COSV101183130; called by muse, mutect2, varscan2
- AHNAK2 | c.3670G>A p.A1224T | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.03); catalogued as rs568360217, COSV100317903; called by muse, mutect2, varscan2
- AJUBA | c.1404A>T p.Q468H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV99401052; called by muse, mutect2, varscan2
- AKNA | c.2846+1G>A p.X949_splice | Splice Site (SNP) | VAF 46/78 reads (59%) | catalogued as rs1198998035, COSV99800543; called by muse, mutect2, varscan2
- AKNA | c.2846G>T p.S949I | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1372962797, COSV99800548; called by muse, mutect2, varscan2
- ALOX5AP | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as COSV100996298; called by muse, mutect2, varscan2
- ANGEL1 | c.589A>G p.I197V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99200428; called by muse, mutect2, varscan2
- ANGPT2 | c.444+2T>C p.X148_splice | Splice Site (SNP) | VAF 38/108 reads (35%) | catalogued as COSV100290986; called by muse, mutect2, varscan2
- ANKRD30A | c.2869G>T p.D957Y (on ENST00000611781; = p.D901Y on NM_052997.2) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1193756258, COSV64621471; called by muse, mutect2, varscan2
- ANKS1B | c.3101G>T p.R1034L (on ENST00000547776 / NM_152788.4; = p.R200L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59117456, COSV59118135; called by muse, mutect2, varscan2
- ANO3 | c.2407C>A p.P803T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99883469; called by muse, mutect2, varscan2
- APOA1 | c.411G>C p.E137D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV99369307; called by muse, mutect2, varscan2
- ARHGAP12 | c.1091G>T p.W364L | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100260659; called by muse, mutect2, varscan2
- ARID1A | c.3871G>T p.E1291* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV61378502; called by muse, mutect2
- ATP10D | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99905736; called by muse, mutect2, varscan2
- ATP13A5 | c.1841C>G p.A614G | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.348); catalogued as COSV100665294; called by muse, mutect2, varscan2
- ATP13A5 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.217); catalogued as rs1196723875, COSV100665296; called by muse, mutect2, varscan2
- ATP5MC2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as COSV100101017; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 64/90 reads (71%) | SIFT tolerated (0.62); PolyPhen benign (0.112); catalogued as COSV99231178; called by muse, mutect2, varscan2
- ATP8B2 | c.3091G>T p.A1031S (on ENST00000672630; = p.A998S on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.854); catalogued as COSV100528052, COSV59248628; called by muse, mutect2, varscan2
- AVPR1A | c.1057G>T p.G353C | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100146869; called by muse, mutect2, varscan2
- AVPR1A | c.518C>G p.A173G | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV100146870, COSV54546488; called by muse, mutect2, varscan2
- AVPR1B | c.878G>C p.C293S | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100899390; called by muse, mutect2, varscan2
- AXIN1 | c.2446A>T p.K816* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99249971; called by muse, mutect2, varscan2
- BCAS4 | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99372582; called by muse, mutect2, varscan2
- BCAS4 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99372583; called by muse, mutect2, varscan2
- BCL11A | c.2226C>A p.N742K (on ENST00000335712 / NM_001365609.1; = p.N776K on NM_022893.4) | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100185856; called by muse, mutect2, varscan2
- BCL11A | c.668G>T p.G223V (on ENST00000335712 / NM_001365609.1; = p.G257V on NM_018014.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100185858; called by muse, mutect2, varscan2
- BPIFB3 | c.1323C>T p.N441= | Splice Region (SNP) | VAF 8/84 reads (10%) | catalogued as rs764502424, COSV64956772; called by muse, mutect2, varscan2
- C19orf47 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100775108; called by muse, mutect2, varscan2
- C1GALT1C1 | c.63G>T p.L21F | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100485624; called by muse, mutect2, varscan2
- CACNA2D1 | c.1466G>T p.G489V | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100666802; called by muse, mutect2, varscan2
- CACNA2D4 | c.2022G>T p.L674F | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV99765857; called by muse, mutect2
- CALB1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55369102; called by muse, mutect2
- CAMKK1 | c.1507G>T p.A503S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.018); catalogued as rs752473571, COSV99340355; called by muse, varscan2
- CAMTA1 | c.2212G>T p.G738C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as COSV100349098, COSV100350713; called by muse, mutect2, varscan2
- CBY2 | c.59C>A p.T20N | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100137658; called by muse, mutect2, varscan2
- CCT4 | c.1126-1G>T p.X376_splice | Splice Site (SNP) | VAF 29/88 reads (33%) | catalogued as COSV101075254; called by muse, mutect2, varscan2
- CD44 | c.2122G>T p.E708* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99555818; called by muse, mutect2, varscan2
- CD5L | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.209); catalogued as COSV100941070, COSV63820977, COSV63821569; called by muse, mutect2, varscan2
- CD84 | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100246094; called by muse, mutect2, varscan2
- CDH13 | c.1010C>A p.A337D | Missense Mutation (SNP) | VAF 160/233 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as rs749237040, COSV99227144; called by muse, mutect2, varscan2
- CDH23 | c.6887T>C p.F2296S | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV99821726; called by muse, mutect2, varscan2
- CDH6 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as rs1325334125, COSV99419575; called by muse, mutect2, varscan2
- CEP164 | c.2028G>T p.Q676H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV54037904, COSV99633633; called by muse, mutect2, varscan2
- CEP192 | c.6634A>G p.I2212V | Missense Mutation (SNP) | VAF 54/80 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV100381455, COSV58065666; called by muse, mutect2, varscan2
- CHORDC1 | c.848G>T p.W283L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV100272079; called by muse, mutect2
- CHPF | c.2083T>C p.S695P | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.295); catalogued as COSV99705056; called by muse, mutect2, varscan2
- CHRNA4 | c.747C>A p.N249K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100937436; called by muse, mutect2, varscan2
- CHST1 | c.620C>A p.T207K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1354494827, COSV100346299, COSV57325184; called by muse, mutect2, varscan2
- CHST9 | c.863C>G p.S288* | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as rs751346125, COSV99410316; called by muse, mutect2, varscan2
- CHSY3 | c.2384G>C p.G795A | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100519361; called by muse, mutect2, varscan2
- CLEC1A | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs773458345, COSV100191515; called by muse, mutect2, varscan2
- CLEC4C | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as COSV100665476; called by muse, mutect2, varscan2
- CLSPN | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99231064; called by muse, mutect2, varscan2
- CNGB1 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); catalogued as rs1287263774, COSV99203103; called by muse, mutect2, varscan2
- CNOT4 | c.629G>C p.C210S | Missense Mutation (SNP) | VAF 71/131 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV100211762; called by muse, mutect2, varscan2
- CNST | c.956G>C p.G319A | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV100830070; called by muse, mutect2, varscan2
- COL11A1 | c.2779G>T p.V927F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.969); catalogued as COSV100617049; called by muse, mutect2, varscan2
- COL6A6 | c.2104G>T p.G702C | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100650403; called by muse, mutect2, varscan2
- COL9A2 | c.418-1G>T p.X140_splice | Splice Site (SNP) | VAF 23/68 reads (34%) | catalogued as COSV101025721; called by muse, mutect2, varscan2
- CPA3 | c.327T>G p.D109E | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99936212; called by muse, mutect2, varscan2
- CPA3 | c.681G>T p.W227C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99936213; called by muse, mutect2, varscan2
- CREB1 | c.347A>G p.D116G (on ENST00000432329 / NM_134442.5; = p.D102G on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.171); catalogued as rs387906617, CM122718, COSV100783588; ClinVar: uncertain significance; called by muse, mutect2
- CRYBG2 | c.1150A>G p.T384A | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.033); catalogued as rs1385309352; called by muse, mutect2, varscan2
- CSMD3 | c.10457C>A p.P3486Q (on ENST00000297405 / NM_001363185.1; = p.P3317Q on NM_052900.3) | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99837373; called by muse, mutect2, varscan2
- CSMD3 | c.10456C>A p.P3486T (on ENST00000297405 / NM_001363185.1; = p.P3317T on NM_052900.3) | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as rs536329289, COSV52345333; called by muse, mutect2, varscan2
- CSMD3 | c.1915C>A p.L639M (on ENST00000297405 / NM_001363185.1; = p.L535M on NM_052900.3) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99837377; called by muse, mutect2, varscan2
- CSTF2T | c.130A>T p.S44C | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100484240; called by muse, mutect2, varscan2
- CTNNA2 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV63580509, COSV63602631; called by muse, mutect2, varscan2
- DCAF10 | c.511G>T p.V171F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV99647758; called by muse, varscan2
- DDX23 | c.1812G>T p.M604I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV99974947; called by muse, mutect2, varscan2
- DGKK | c.2980C>A p.H994N | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs1557224053, COSV101053067; called by muse, mutect2
- DHCR7 | c.923G>T p.W308L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100831977; called by muse, mutect2, varscan2
- DIAPH3 | c.1225G>T p.D409Y (on ENST00000400324 / NM_001042517.2; = p.D146Y on NM_030932.3) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99933780; called by muse, mutect2, varscan2
- DIO2 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as rs1158536632, COSV101375898; called by muse, mutect2
- DLGAP2 | c.1414G>T p.G472* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV101422136, COSV70102290; called by muse, mutect2
- DNAH11 | c.8333T>A p.M2778K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as COSV100179555, COSV100181322; called by muse, mutect2, varscan2
- DNAH5 | c.4086G>T p.Q1362H | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV54214264, COSV99450891; called by muse, mutect2, varscan2
- DNAH9 | c.6814C>T p.R2272C | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as rs139421775; called by muse, mutect2, varscan2
- DOC2A | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV58751192; called by muse, mutect2, varscan2
- DSCAM | c.4492G>A p.G1498S | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV101260504; called by muse, mutect2, varscan2
- DYNC2H1 | c.2205G>T p.Q735H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100518810; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1212A>T p.Q404H (on ENST00000361735 / NM_015935.5; = p.Q318H on NM_014955.3) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV100675919; called by muse, mutect2, varscan2
- EIF2AK4 | c.2143G>A p.G715S | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1363955113, COSV99774854; called by muse, mutect2, varscan2
- EIF2AK4 | c.4744G>T p.E1582* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV99139551; called by muse, mutect2, varscan2
- EPHA3 | c.1100G>C p.G367A | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.64); PolyPhen benign (0.298); catalogued as rs760852634, COSV100346095; called by muse, mutect2, varscan2
- EPHA5 | c.3078G>A p.M1026I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as COSV56643114, COSV56666361; called by muse, mutect2, varscan2
- EPHA5 | c.2896G>T p.A966S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99899543; called by muse, mutect2, varscan2
- ERICH6 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs370477652; called by muse, mutect2, varscan2
- ERLEC1 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 32/172 reads (19%) | catalogued as rs1442170971, COSV51752235, COSV99483076; called by muse, mutect2, varscan2
- ESPNL | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100547842; called by muse, mutect2, varscan2
- ESX1 | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101006477; called by muse, mutect2
- ETS1 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100090899; called by muse, mutect2, varscan2
- EXD3 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as rs1463316686, COSV100573773; called by muse, mutect2, varscan2
- FAM104A | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.282); catalogued as COSV99278192; called by muse, mutect2, varscan2
- FAM135A | c.1871A>G p.D624G (on ENST00000370479 / NM_001351599.1; = p.D411G on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV99525971; called by muse, mutect2, varscan2
- FAM184A | c.1443G>C p.K481N | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1401843172, COSV100137958; called by muse, mutect2, varscan2
- FAM71F1 | c.180C>A p.C60* | Nonsense Mutation (SNP) | VAF 35/75 reads (47%) | catalogued as COSV100171041; called by muse, mutect2, varscan2
- FANCM | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs141729590, CM1512826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FARSB | c.1619-2A>T p.X540_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99918448; called by muse, mutect2
- FBXL4 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 57/82 reads (70%) | catalogued as COSV100014192; called by muse, mutect2, varscan2
- FGD4 | c.2283G>T p.K761N | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV56781315; called by muse, mutect2, varscan2
- FHDC1 | c.620A>G p.E207G | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99471398; called by muse, mutect2, varscan2
- FLG | c.11645C>A p.S3882Y | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV100911674; called by muse, mutect2, varscan2
- FLG2 | c.273A>T p.K91N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101165950; called by muse, mutect2, varscan2
- FOXD4L5 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV101073186; called by muse, mutect2, varscan2
- FOXN3 | c.338G>T p.C113F | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV99726691; called by muse, mutect2, varscan2
- FOXP1 | c.1297G>T p.G433* | Nonsense Mutation (SNP) | VAF 40/85 reads (47%) | catalogued as COSV100561873; called by muse, mutect2, varscan2
- FRMD1 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 60/94 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374394474, COSV99349853; called by muse, mutect2, varscan2
- FRY | c.7439A>T p.N2480I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100969410; called by muse, mutect2, varscan2
- FUS | c.1546G>T p.E516* | Nonsense Mutation (SNP) | VAF 37/50 reads (74%) | catalogued as rs1236915806, COSV54218851, COSV99568743; called by muse, mutect2, varscan2
- FUS | c.1547A>C p.E516A | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as COSV99568746; called by muse, mutect2, varscan2
- FUT6 | c.734C>A p.A245D | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99744699; called by muse, mutect2, varscan2
- FUT6 | c.285C>A p.D95E | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV99744702; called by muse, mutect2, varscan2
- GALNT13 | c.1648A>T p.R550W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV101223301; called by muse, mutect2, varscan2
- GAPT | c.419G>C p.R140P | Missense Mutation (SNP) | VAF 54/77 reads (70%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV100576318; called by muse, mutect2, varscan2
- GFRA3 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 38/58 reads (66%) | catalogued as rs1434964537, COSV99218342, COSV99218430; called by muse, mutect2, varscan2
- GLB1L2 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100335392; called by muse, mutect2, varscan2
- GLDC | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV100394260; called by muse, mutect2, varscan2
- GLP1R | c.1113G>T p.M371I | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100952627, COSV64714565; called by muse, mutect2, varscan2
- GON4L | c.3317C>A p.A1106D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV99674681; called by muse, mutect2, varscan2
- GPR26 | c.288C>A p.S96R | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs780657449, COSV99500965; called by muse, varscan2
- GRIA4 | c.2665A>G p.R889G | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1449011984, COSV99232333; called by muse, mutect2, varscan2
- GRID2 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.885); catalogued as COSV99942134; called by muse, mutect2, varscan2
- GRIP2 | c.3377G>C p.S1126T (on ENST00000619221; = p.S1029T on NM_001080423.4) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99817424; called by muse, mutect2, varscan2
- GRK7 | c.1516A>C p.K506Q | Missense Mutation (SNP) | VAF 169/341 reads (50%) | SIFT tolerated (0.81); PolyPhen benign (0.013); catalogued as COSV99379959; called by muse, mutect2, varscan2
- HECW2 | c.2216G>T p.R739L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.982); catalogued as rs201414655, COSV99647544; called by muse, mutect2, varscan2
- HIPK3 | c.2855C>T p.S952F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs371278906; called by muse, mutect2, varscan2
- HLA-DRA | c.700G>T p.G234W | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457000781, COSV100895077; called by muse, mutect2, varscan2
- HOMEZ | c.1349A>G p.E450G | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as COSV100664123; called by muse, mutect2
- HOXC10 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV100328972, COSV57727340; called by muse, mutect2, varscan2
- HSPG2 | c.8755C>T p.P2919S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.293); catalogued as COSV65934096, COSV65934212; called by muse, mutect2, varscan2
- HTR3B | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV52744585, COSV99492050; called by muse, mutect2, varscan2
- ICE1 | c.3080C>T p.S1027F | Missense Mutation (SNP) | VAF 67/101 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV99664984; called by muse, mutect2, varscan2
- IGDCC4 | c.3583G>T p.D1195Y | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV100732957, COSV61539790; called by muse, mutect2, varscan2
- IGHMBP2 | c.1513G>C p.D505H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99662180; called by muse, mutect2, varscan2
- IGSF9B | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.042); catalogued as COSV58068362; called by muse, mutect2, varscan2
- IL13RA2 | c.816T>G p.Y272* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99683158; called by muse, mutect2, varscan2
- IL33 | c.776G>T p.C259F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as COSV101197896; called by muse, mutect2, varscan2
- IMPG2 | c.3214G>T p.G1072W | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99515755; called by muse, mutect2, varscan2
- IQCN | c.2617-1G>T p.X873_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as rs1242860333, COSV100828315; called by muse, mutect2, varscan2
- ITK | c.395G>T p.C132F | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101439789; called by muse, mutect2, varscan2
- ITPR2 | c.7007G>T p.G2336V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101190038; called by muse, mutect2, varscan2
- KALRN | c.7562A>T p.Y2521F (on ENST00000360013 / NM_001024660.4; = p.Y824F on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.458); catalogued as COSV99362287; called by muse, mutect2, varscan2
- KANSL1L | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs927191230, COSV99910658; called by muse, mutect2, varscan2
- KCNH1 | c.103G>C p.A35P | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165808410, COSV55094350, COSV99659737; called by muse, mutect2, varscan2
- KCNK10 | c.723G>T p.L241F | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100068634; called by muse, mutect2, varscan2
- KDM2A | c.2479G>C p.A827P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV100445674; called by muse, mutect2, varscan2
- KEAP1 | c.1478A>T p.E493V | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as COSV50662067, COSV99407918; called by muse, mutect2, varscan2
- KIAA0319 | c.996G>T p.V332= | Splice Region (SNP) | VAF 26/33 reads (79%) | catalogued as COSV100985638; called by muse, mutect2, varscan2
- KIF27 | c.38G>T p.R13I | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99927059; called by muse, mutect2, varscan2
- KLK9 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.7); catalogued as rs1452521765, COSV99144003; called by muse, mutect2, varscan2
- KMT2D | c.2377G>T p.E793* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | catalogued as rs1360040004, COSV99979233, COSV99981950; called by muse, mutect2, varscan2
- KYNU | c.1106A>T p.E369V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV99933413; called by muse, mutect2, varscan2
- LBR | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as rs541202772, COSV99687481; called by muse, mutect2
- LCE1A | c.226A>T p.R76W | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1353448880, COSV100632095; called by muse, mutect2, varscan2
- LCP2 | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs1329258017, COSV99252962; called by muse, mutect2, varscan2
- LCT | c.3097T>G p.W1033G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929723; called by muse, mutect2, varscan2
- LEP | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100451438; called by muse, mutect2, varscan2
- LHFPL4 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as COSV55000661; called by muse, mutect2, varscan2
- LMLN | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as rs1242168735, COSV100218652; called by muse, mutect2, varscan2
- LPL | c.99T>A p.D33E | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV100255644; called by muse, mutect2, varscan2
- LRAT | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV100312114; called by muse, mutect2, varscan2
- LRATD1 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99707178; called by muse, mutect2, varscan2
- LRFN3 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1477863802, COSV55817019, COSV99873408; called by muse, mutect2, varscan2
- LRIF1 | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV100870864; called by muse, mutect2, varscan2
- LRP1 | c.11461G>A p.G3821R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs761581181, COSV54517448; called by muse, mutect2
- LRP8 | c.1800G>T p.W600C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036613; called by muse, mutect2, varscan2
- LRRC42 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.695); catalogued as COSV100066232, COSV59960239, COSV59960522; called by muse, mutect2, varscan2
- LRRC56 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV99530308; called by muse, mutect2, varscan2
- LRRTM1 | c.80C>A p.A27D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV54440451, COSV99702707; called by muse, mutect2, varscan2
- LZTS3 | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as rs1215821210, COSV100232310; called by muse, mutect2, varscan2
- MACO1 | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100975199; called by muse, mutect2, varscan2
- MAGEB18 | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1015908588, COSV100305508; called by muse, mutect2, varscan2
- MAGEB4 | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1190350621, COSV100975022; called by muse, mutect2, varscan2
- MAGI2 | c.1947C>G p.I649M | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100834982; called by muse, mutect2, varscan2
- MAPKAP1 | c.1234G>C p.D412H (on ENST00000265960 / NM_001006617.3; = p.D376H on NM_024117.3) | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99785156; called by muse, mutect2, varscan2
- MAPKBP1 | c.2915T>A p.V972E (on ENST00000456763 / NM_001128608.2; = p.V966E on NM_014994.3) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1302519407, COSV99529694; called by muse, mutect2, varscan2
- MARK4 | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99488435; called by muse, mutect2, varscan2
- MARS2 | c.1091G>T p.R364L | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs749816014, COSV99986617; called by muse, mutect2, varscan2
- MCM5 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as COSV53346220, COSV99331765; called by muse, mutect2, varscan2
- MDGA2 | c.2881C>T p.Q961* (on ENST00000399232 / NM_001113498.2; = p.Q663* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as COSV62091554; called by muse, mutect2, varscan2
- MDGA2 | c.1514C>T p.S505F (on ENST00000399232 / NM_001113498.2; = p.S207F on NM_182830.4) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100637432; called by muse, mutect2, varscan2
- MED12 | c.1996A>G p.M666V | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.226); catalogued as rs1401003961, COSV61354068; called by muse, mutect2, varscan2
- MEF2C | c.1130G>T p.S377I | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs1194276851, COSV100425527; called by muse, mutect2, varscan2
- MKI67 | c.8042G>T p.G2681V | Missense Mutation (SNP) | VAF 69/120 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100896675; called by muse, mutect2, varscan2
- MPP2 | c.1092G>T p.E364D (on ENST00000461854 / NM_001278372.2; = p.E340D on NM_005374.5) | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166548868, COSV52235123, COSV99290501; called by muse, mutect2, varscan2
- MPP7 | c.1711G>T p.V571L | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV100517508; called by muse, mutect2, varscan2
- MS4A5 | c.513G>C p.M171I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV100281041; called by muse, mutect2
- MSRB3 | c.502C>G p.P168A | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV57591804; called by muse, mutect2, varscan2
- MTBP | c.605C>G p.T202S | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.833); catalogued as rs747605278, COSV100012239; called by muse, mutect2
- MTF1 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100888657; called by muse, mutect2, varscan2
- MTMR1 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100953113; called by muse, mutect2, varscan2
- MTNR1B | c.760T>C p.F254L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV99925175; called by muse, mutect2, varscan2
- MUC16 | c.41469G>T p.Q13823H | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV101109941; called by muse, mutect2, varscan2
- MUC16 | c.40613C>G p.P13538R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101109942; called by muse, mutect2, varscan2
- MUC16 | c.25492G>T p.E8498* | Nonsense Mutation (SNP) | VAF 70/124 reads (56%) | catalogued as COSV101200229, COSV101201403; called by muse, mutect2, varscan2
- MUC16 | c.18997G>T p.V6333F | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.354); catalogued as COSV101200230; called by muse, mutect2, varscan2
- MUC3A | c.8606G>T p.S2869I | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs766074974, COSV100114791; called by muse, mutect2
- MUC5B | c.7918C>G p.P2640A | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101500441; called by muse, mutect2, varscan2
- MYH15 | c.1293+1G>C p.X431_splice | Splice Site (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99843508; called by muse, mutect2, varscan2
- MYH4 | c.1233T>A p.N411K | Missense Mutation (SNP) | VAF 52/86 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99701517; called by muse, mutect2, varscan2
- MYLK2 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV101044824; called by muse, mutect2
- MYO5B | c.3344C>T p.S1115F | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV99545366; called by muse, mutect2, varscan2
- MYO5B | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99545368; called by muse, mutect2, varscan2
- MYOCD | c.2444G>A p.S815N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.995); catalogued as COSV100590921; called by muse, mutect2, varscan2
- MYOD1 | c.936C>G p.N312K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100000292; called by muse, mutect2, varscan2
- MYOF | c.832G>T p.G278W | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825843; called by muse, mutect2, varscan2
- NAV2 | c.2999A>T p.Q1000L (on ENST00000396087 / NM_001244963.2; = p.Q977L on NM_145117.5) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.108); catalogued as COSV100217169, COSV60658867; called by muse, mutect2, varscan2
- NBAS | c.5944G>T p.E1982* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as COSV99870283; called by muse, mutect2, varscan2
- NCAM2 | c.1642C>A p.H548N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.319); catalogued as COSV53069880; called by muse, mutect2, varscan2
- NCAM2 | c.1643A>T p.H548L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV99523509; called by muse, mutect2, varscan2
- NEDD4L | c.1214A>G p.N405S (on ENST00000400345 / NM_001144967.3; = p.N385S on NM_015277.6) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1330224857, COSV56847837; called by muse, mutect2, varscan2
- NFASC | c.2711C>A p.T904K (on ENST00000339876 / NM_001378329.1; = p.T1007K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100364298, COSV58360528; called by muse, mutect2, varscan2
- NIN | c.3647G>C p.R1216P | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as COSV99813896; called by muse, mutect2, varscan2
- NLGN4Y | c.2267G>A p.C756Y | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV100196891; called by muse, mutect2, varscan2
- NLRP14 | c.2805-1G>T p.X935_splice | Splice Site (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100205119; called by muse, mutect2, varscan2
- NOTCH2 | c.5840C>T p.P1947L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99864722; called by muse, mutect2, varscan2
- NRAP | c.4795C>T p.Q1599* (on ENST00000359988 / NM_001322945.2; = p.Q1564* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100667968; called by muse, mutect2, varscan2
- NRDE2 | c.3059T>G p.F1020C | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100583519; called by muse, mutect2, varscan2
- OPN1SW | c.317T>A p.V106D | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); catalogued as rs139477114, COSV99975729; called by muse, mutect2, varscan2
- OR10A2 | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1206660388, COSV100225073; called by muse, mutect2
- OR10K2 | c.765del p.S256Pfs*5 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | catalogued as COSV59221585; called by mutect2, pindel, varscan2
- OR13H1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV100088306; called by muse, mutect2, varscan2
- OR1J4 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 74/117 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100534293; called by muse, mutect2, varscan2
- OR2A5 | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs1214801513, COSV101278772; called by muse, mutect2, varscan2
- OR2L13 | c.246C>A p.Y82* | Nonsense Mutation (SNP) | VAF 42/106 reads (40%) | catalogued as COSV100813794; called by muse, mutect2, varscan2
- OR2T10 | c.678T>G p.H226Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.098); catalogued as COSV100393735; called by muse, mutect2, varscan2
- OR2T3 | c.298T>A p.S100T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100613267; called by muse, mutect2, varscan2
- OR4C11 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV56352271; called by muse, mutect2, varscan2
- OR4C15 | c.938G>A p.R313Q (on ENST00000314644; = p.R259Q on NM_001001920.2) | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.493); catalogued as rs149965163, COSV58952933, COSV58954574; called by muse, mutect2, varscan2
- OR4C3 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333318747, COSV100167948; called by muse, mutect2, varscan2
- OR4C3 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV100167950; called by muse, mutect2, varscan2
- OR4S2 | c.809C>G p.A270G | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100412697, COSV100412828; called by muse, mutect2
- OR51B5 | c.508C>A p.H170N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as rs1379574719, COSV100332571; called by muse, mutect2, varscan2
- OR51B6 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs746693331, COSV100971457; called by muse, mutect2, varscan2
- OR51T1 | c.158C>A p.T53N | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV100434422; called by muse, mutect2, varscan2
- OR52N4 | c.436del p.V146Lfs*7 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as COSV57890652; called by pindel, varscan2
- OR5AP2 | c.748T>A p.Y250N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100266266; called by muse, mutect2, varscan2
- OR5B17 | c.882C>A p.D294E | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100641914; called by muse, mutect2, varscan2
- OR5B17 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.175); catalogued as COSV100641916; called by muse, mutect2, varscan2
- OR5D16 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as rs745349872, COSV101004013, COSV65722331; called by muse, mutect2, varscan2
- OR5K3 | c.447C>A p.Y149* | Nonsense Mutation (SNP) | VAF 70/123 reads (57%) | catalogued as rs761691929, COSV101051655; called by muse, mutect2, varscan2
- OR6C2 | c.74T>A p.L25H | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as COSV100498723; called by muse, mutect2, varscan2
- OR8K1 | c.414C>G p.Y138* | Nonsense Mutation (SNP) | VAF 54/149 reads (36%) | catalogued as rs757496734, COSV99687132, COSV99687376; called by muse, mutect2, varscan2
- OR8U1 | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.098); catalogued as COSV100163976, COSV56416047; called by muse, mutect2, varscan2
- OR9A2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV63306405; called by muse, mutect2
- OR9Q1 | c.691G>T p.G231* | Nonsense Mutation (SNP) | VAF 52/136 reads (38%) | catalogued as COSV100110107; called by muse, mutect2, varscan2
- OSBPL6 | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.99); catalogued as COSV99507715; called by muse, mutect2, varscan2
- OTOS | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99048167; called by muse, mutect2
- P3H2 | c.1552G>T p.G518C | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1323178173, COSV100077878; called by muse, mutect2, varscan2
- PARP16 | c.409A>T p.K137* | Nonsense Mutation (SNP) | VAF 23/37 reads (62%) | catalogued as COSV99975533; called by muse, mutect2, varscan2
- PCCB | c.646A>G p.M216V | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs747252352, COSV52448273, COSV99291439; called by muse, mutect2, varscan2
- PCDH11Y | c.1599C>G p.I533M (on ENST00000400457 / NM_032973.2; = p.I522M on NM_032971.3) | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99291718; called by muse, mutect2, varscan2
- PCDHB12 | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 64/97 reads (66%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); catalogued as COSV99507408; called by muse, mutect2, varscan2
- PCDHGA10 | c.1454G>T p.S485I | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV99540455; called by muse, mutect2, varscan2
- PCDHGA5 | c.308T>A p.V103E | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.392); catalogued as COSV99540454; called by muse, mutect2, varscan2
- PCDHGB2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV99535226; called by muse, mutect2, varscan2
- PCLO | c.12637G>C p.E4213Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100433784, COSV61654667; called by muse, mutect2, varscan2
- PDIA4 | c.1223A>T p.K408M (on ENST00000286091 / NM_001371244.1; = p.K407M on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV99618627; called by muse, mutect2
- PDYN | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV99453103; called by muse, mutect2, varscan2
- PDZRN4 | c.2536C>A p.H846N (on ENST00000402685 / NM_001164595.2; = p.H588N on NM_013377.4) | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs1392993194, COSV100114770; called by muse, mutect2, varscan2
- PFKL | c.1958G>T p.C653F | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100297175; called by muse, mutect2, varscan2
- PLEC | c.9375G>T p.E3125D (on ENST00000322810 / NM_201380.4; = p.E3015D on NM_000445.5) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1435998343, COSV100509962; called by muse, mutect2, varscan2
- PLEKHG1 | c.4001T>A p.V1334D | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV100651708; called by muse, mutect2, varscan2
- PLSCR4 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV100724244; called by muse, mutect2
- PLXNA4 | c.3685G>T p.A1229S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100324960; called by muse, mutect2, varscan2
- POLR2A | c.3143C>T p.T1048M | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.558); catalogued as rs755560039; called by muse, mutect2, varscan2
- POSTN | c.1234G>C p.A412P | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764694291, COSV101123379; called by muse, mutect2, varscan2
- PPM1E | c.721C>G p.R241G | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100376351; called by muse, mutect2, varscan2
- PPP1R1A | c.233C>A p.T78K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV99226418; called by muse, mutect2, varscan2
- PRAG1 | c.4013A>T p.Q1338L | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV100422344; called by muse, mutect2, varscan2
- PRB2 | c.1163C>G p.P388R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV101231437, COSV66982844; called by mutect2, varscan2
- PRB3 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs148496066; called by muse, mutect2, varscan2
- PREX1 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1335093360, COSV100906478; called by muse, mutect2, varscan2
- PRSS12 | c.1333A>G p.T445A | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs775780789, COSV99628392; called by muse, mutect2, varscan2
- PSORS1C1 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs540640358, COSV99456141; called by muse, mutect2, varscan2
- PTGER3 | c.1082G>T p.R361M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV100139113; called by muse, mutect2, varscan2
- PTPN12 | c.587A>T p.N196I | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99950434; called by muse, mutect2, varscan2
- PTPRH | c.2080G>T p.E694* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV54743214, COSV99670778; called by muse, mutect2, varscan2
- PTPRO | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99840838; called by muse, mutect2, varscan2
- PYHIN1 | c.768C>A p.N256K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100932364; called by muse, mutect2, varscan2
- R3HDM1 | c.498G>T p.R166S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs1278919791, COSV99925814; called by muse, mutect2, varscan2
- RASAL3 | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV99653375; called by muse, mutect2, varscan2
- RASEF | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100525592; called by muse, varscan2
- RBBP6 | c.983A>G p.Y328C | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs368305107, COSV100154675; called by muse, mutect2, varscan2
- RBM19 | c.2823G>C p.E941D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV99926246; called by muse, mutect2, varscan2
- RBM19 | c.2558+1G>C p.X853_splice | Splice Site (SNP) | VAF 19/112 reads (17%) | catalogued as COSV99926248; called by muse, mutect2, varscan2
- RETNLB | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.692); catalogued as rs1346687824, COSV55465311, COSV99848819; called by muse, mutect2, varscan2
- RIC8B | c.214A>T p.I72F | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62695552; called by muse, mutect2, varscan2
- RNF112 | c.1684G>C p.A562P | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV101465419; called by muse, mutect2, varscan2
- ROR2 | c.395A>T p.Y132F | Missense Mutation (SNP) | VAF 62/95 reads (65%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs766409977, COSV100995885; called by muse, mutect2, varscan2
- RPH3A | c.601C>A p.P201T (on ENST00000389385 / NM_001143854.2; = p.P197T on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101231836; called by muse, mutect2, varscan2
- RYR2 | c.5038G>A p.V1680M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV100771091; called by muse, mutect2, varscan2
- RYR2 | c.5482C>A p.L1828M | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs754589083, COSV100771093; called by muse, mutect2, varscan2
- RYR2 | c.13170G>T p.Q4390H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV100771099; called by muse, mutect2, varscan2
- RYR3 | c.341C>A p.S114Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as COSV101213034, COSV66777888, COSV66809105; called by muse, mutect2, varscan2
- SCARA5 | c.253C>A p.R85S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs1247889500, COSV100107937; called by muse, mutect2
- SCN4A | c.2764A>G p.I922V | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1273256363, COSV101438529; called by muse, mutect2, varscan2
- SCN7A | c.4408T>A p.S1470T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs776614707, COSV101313265; called by muse, mutect2, varscan2
- SDC2 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100143596; called by muse, mutect2, varscan2
- SEC22C | c.77A>T p.H26L | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV99827503; called by muse, mutect2, varscan2
- SEMG2 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV65647312; called by muse, mutect2, varscan2
- SENP7 | c.2867A>T p.Y956F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100053404; called by mutect2, varscan2
- SENP7 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 31/112 reads (28%) | catalogued as rs1235701314, COSV100053407; called by muse, mutect2, varscan2
- SHANK1 | c.1222G>T p.V408L | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99521436; called by muse, mutect2, varscan2
- SHANK1 | c.197A>T p.D66V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99521438; called by muse, mutect2, varscan2
- SIGLEC14 | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1270949897, COSV99707599; called by muse, mutect2, varscan2
- SIGLEC6 | c.327A>T p.R109S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100585481; called by muse, mutect2, varscan2
- SLC1A6 | c.1213C>A p.L405M | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.405); catalogued as COSV55669341, COSV55671205, COSV99693857; called by muse, mutect2, varscan2
- SLC35E4 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100299244; called by muse, mutect2, varscan2
- SLC44A5 | c.1976G>T p.G659V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1469685280, COSV100901837; called by muse, mutect2, varscan2
- SLC49A3 | c.342G>T p.M114I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100448476; called by muse, mutect2, varscan2
- SLC6A12 | c.1691C>A p.P564H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as rs1185489901, COSV100675134; called by muse, mutect2, varscan2
- SLC7A10 | c.1102C>A p.L368I | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99472323; called by muse, mutect2
- SLITRK1 | c.1264C>G p.L422V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1270893720, CD054423, COSV100999989; called by muse, mutect2, varscan2
- SMAD5 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as COSV101548131; called by muse, mutect2
- SMARCA5 | c.1959G>T p.M653I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99303922; called by muse, mutect2, varscan2
- SMYD2 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100873233, COSV65290405; called by muse, mutect2, varscan2
- SPATA13 | c.1654T>G p.W552G | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100542344; called by muse, mutect2, varscan2
- SPATA16 | c.1253C>A p.T418N | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs778578384, COSV100651346; called by muse, mutect2, varscan2
- SPIC | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 120/243 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as rs140558653, COSV54692997; called by muse, mutect2, varscan2
- SPTA1 | c.6456G>T p.Q2152H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100935118; called by muse, mutect2, varscan2
- SSRP1 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99554959; called by muse, mutect2, varscan2
- ST18 | c.1030G>T p.V344F | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.798); catalogued as COSV99390011; called by muse, mutect2, varscan2
- ST18 | c.849C>A p.S283R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52487499, COSV99390014; called by muse, mutect2, varscan2
- STARD13 | c.803G>A p.G268E (on ENST00000336934 / NM_001243476.3; = p.G150E on NM_052851.3) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1344437600, COSV55229035; called by muse, mutect2, varscan2
- SUDS3 | c.318C>G p.Y106* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as rs1479840725, COSV101288558; called by muse, mutect2, varscan2
- SYNE2 | c.2031dup p.Q678Tfs*7 | Frame Shift Ins (INS) | VAF 15/107 reads (14%) | catalogued as rs750736888; ClinVar: uncertain significance; called by mutect2, varscan2
- SYNE2 | c.13519G>A p.D4507N | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.78); catalogued as COSV100647936; called by muse, mutect2, varscan2
- TACC1 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV99393593; called by muse, mutect2, varscan2
- TAS2R20 | c.759G>C p.K253N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV101115005; called by muse, mutect2, varscan2
- TBC1D9 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764794465, COSV101464359; called by muse, mutect2, varscan2
- TBL1XR1 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1171215975, COSV101467774; called by muse, mutect2
- TBL1XR1 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.542); catalogued as COSV101467775; called by muse, mutect2, varscan2
- TBX22 | c.1150C>A p.Q384K | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs1353576298, COSV100960839; called by muse, mutect2, varscan2
- TENM1 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 71/93 reads (76%) | SIFT tolerated (0.69); PolyPhen benign (0.019); catalogued as rs928389720, COSV64436860; called by muse, mutect2, varscan2
- TENM3 | c.3026C>A p.S1009Y | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101305193, COSV101305553; called by muse, mutect2, varscan2
- TESPA1 | c.1534C>T p.H512Y (on ENST00000316577 / NM_001098815.3; = p.H374Y on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV100345324; called by muse, mutect2
- TET3 | c.815G>A p.C272Y | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996403; called by muse, mutect2, varscan2
- TGDS | c.652A>T p.R218W | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54301076, COSV99725152; called by muse, mutect2, varscan2
- TGIF2LX | c.538A>G p.S180G | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV99383423; called by muse, mutect2, varscan2
- THEMIS | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 112/163 reads (69%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100965426; called by muse, mutect2, varscan2
- TKTL2 | c.1413G>T p.M471I | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1432263406, COSV99761485; called by muse, mutect2, varscan2
- TLE4 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 29/39 reads (74%) | catalogued as COSV99512391; called by muse, mutect2, varscan2
- TMEM132B | c.1993G>C p.V665L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs1034128891, COSV100170015; called by muse, mutect2, varscan2
- TMEM132E | c.379C>G p.R127G | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100396468, COSV58701591; called by muse, mutect2, varscan2
- TMEM132E | c.525A>G p.E175= | Splice Region (SNP) | VAF 10/14 reads (71%) | catalogued as rs1383554001, COSV100396471; called by muse, varscan2
- TMPRSS15 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs1266329301, COSV99518251; called by muse, mutect2, varscan2
- TNFRSF17 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs561432842, COSV99273279; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1525G>T p.A509S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.441); catalogued as COSV100836103; called by muse, mutect2, varscan2
- TNNI3K | c.1473-2A>T p.X491_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100436981; called by muse, mutect2, varscan2
- TNRC6C | c.4418G>T p.R1473M | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100050136; called by muse, mutect2, varscan2
- TPTE | c.686G>T p.R229L (on ENST00000618007 / NM_199261.4; = p.R211L on NM_199259.4) | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs566493792; called by muse, mutect2, varscan2
- TRIM56 | c.2002G>T p.V668F | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs1287921868, COSV100047436; called by muse, mutect2, varscan2
- TRIM58 | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); catalogued as COSV100825146; called by muse, mutect2, varscan2
- TSHZ2 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as rs201799053, COSV100296255; called by muse, mutect2, varscan2
- TTN | c.36286G>T p.D12096Y (on ENST00000591111; = p.D4672Y on NM_003319.4) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | PolyPhen probably damaging (0.999); catalogued as COSV100617908; called by muse, mutect2, varscan2
- TTN | c.23321C>T p.P7774L (on ENST00000591111; = p.P6847L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | PolyPhen probably damaging (0.934); catalogued as rs1418085481, COSV100617910; called by muse, mutect2, varscan2
- UBE4A | c.2547G>C p.M849I (on ENST00000252108 / NM_001204077.2; = p.M856I on NM_004788.4) | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV99348322; called by muse, mutect2, varscan2
- USH2A | c.5252G>T p.G1751V | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370995421, CM1110219, COSV100237028; called by muse, mutect2, varscan2
- USP30 | c.393A>T p.E131D | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99980429; called by muse, mutect2, varscan2
- USP34 | c.3065C>G p.S1022C | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs1287208359, COSV101277075; called by muse, mutect2, varscan2
- USP9X | c.1501G>A p.G501S | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100199198, COSV100199498; called by muse, mutect2, varscan2
- VAV2 | c.2588G>T p.R863L (on ENST00000371850 / NM_001134398.2; = p.R824L on NM_003371.4) | Missense Mutation (SNP) | VAF 58/87 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1192809186, COSV100895883; called by muse, mutect2, varscan2
- VAV2 | c.820C>A p.L274I (on ENST00000371850 / NM_001134398.2; = p.L269I on NM_003371.4) | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.999); catalogued as COSV100895885; called by muse, mutect2, varscan2
- VPS13B | c.1735A>G p.I579V | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750419805, COSV100662337; called by muse, mutect2, varscan2
- VPS16 | c.1549G>A p.V517I | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100988509, COSV66794061; called by muse, mutect2, varscan2
- VPS39 | c.475-1G>T p.X159_splice (on ENST00000348544 / NM_001301138.2; = p.X148_splice on NM_015289.5) | Splice Site (SNP) | VAF 28/40 reads (70%) | catalogued as rs1442048091, COSV100529316; called by muse, mutect2, varscan2
- VSIG10 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.756); catalogued as COSV100821301; called by muse, mutect2, varscan2
- WFS1 | c.980T>G p.L327R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99901334; called by muse, mutect2
- WNT7A | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746475689, COSV53199311; called by muse, mutect2, varscan2
- WRN | c.996A>T p.Q332H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV99989259; called by muse, mutect2, varscan2
- WT1 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.059); catalogued as COSV100188321, COSV60082551; called by muse, mutect2, varscan2
- XDH | c.420G>C p.E140D | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.093); catalogued as rs1268924741, COSV101052249; called by muse, mutect2, varscan2
- XIRP2 | c.9044C>T p.A3015V (on ENST00000628543; = p.A3190V on NM_152381.6) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV99744063; called by muse, mutect2, varscan2
- Z83844.2 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100379199; called by muse, mutect2
- ZBTB32 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.526); catalogued as rs749111430, COSV52892796; called by muse, mutect2, varscan2
- ZDBF2 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100985023; called by muse, mutect2, varscan2
- ZDBF2 | c.3329A>T p.E1110V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.282); catalogued as COSV100985024; called by muse, mutect2, varscan2
- ZEB2 | c.1191C>A p.F397L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV100356286; called by muse, mutect2, varscan2
- ZFYVE26 | c.4378G>A p.E1460K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV100720520; called by muse, mutect2, varscan2
- ZNF10 | c.1579A>G p.S527G | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV99940029; called by muse, mutect2, varscan2
- ZNF254 | c.1216T>G p.Y406D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100741670; called by muse, mutect2, varscan2
- ZNF425 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1460987860, COSV100955496; called by muse, mutect2, varscan2
- ZNF462 | c.6317A>G p.H2106R | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99472356; called by muse, mutect2, varscan2
- ZNF479 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs758836813, COSV100482813; called by muse, mutect2, varscan2
- ZNF502 | c.985G>T p.G329W | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99939756; called by muse, mutect2, varscan2
- ZNF518B | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as rs749933748, COSV100456759; called by muse, mutect2, varscan2
- ZNF585A | c.287G>C p.C96S (on ENST00000292841 / NM_001288800.2; = p.C41S on NM_152655.3) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.093); catalogued as rs749294179, COSV99493238; called by muse, mutect2, varscan2
- ZNF598 | c.2363G>A p.G788D | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99937299; called by muse, mutect2, varscan2
- ZNF676 | c.1791A>T p.E597D (on ENST00000650058; = p.E565D on NM_001001411.3) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV101236244; called by muse, mutect2, varscan2
- ZNF681 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV101267489; called by muse, mutect2, varscan2
- ZNF705A | c.748C>G p.H250D | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100828324; called by muse, mutect2, varscan2
- ZNF831 | c.3397T>A p.F1133I | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV100926085; called by muse, mutect2, varscan2
- ZSCAN10 | c.1658G>A p.C553Y (on ENST00000252463; = p.C608Y on NM_032805.3) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252308023, COSV99374123; called by muse, mutect2, varscan2
- ACACA | c.520A>C p.I174L | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- ADGRG3 | c.938del p.G313Vfs*7 | Frame Shift Del (DEL) | VAF 33/60 reads (55%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.4980del p.T1661Pfs*7 | Frame Shift Del (DEL) | VAF 86/153 reads (56%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.8421_8423del p.Q2808del | In Frame Del (DEL) | VAF 18/124 reads (15%) | called by mutect2, pindel, varscan2
- CAMK2A | c.292_295del p.F98Kfs*38 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- FLOT2 | c.693_699+4del p.X231_splice | Splice Site (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel
- GABRR2 | c.741del p.W247Cfs*28 | Frame Shift Del (DEL) | VAF 22/47 reads (47%) | called by mutect2, pindel, varscan2
- IGKV1D-42 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- IGKV3D-20 | c.104C>A p.P35Q | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- KIR3DL3 | c.1162G>C p.V388L | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MYO16 | c.3433C>A p.L1145I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.02); called by muse, mutect2
- NLRP8 | c.1542dup p.A515Cfs*69 | Frame Shift Ins (INS) | VAF 58/145 reads (40%) | called by mutect2, pindel, varscan2
- PALMD | c.1541del p.G514Afs*23 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | called by mutect2, pindel, varscan2
- RASAL2 | c.1097del p.L366* | Frame Shift Del (DEL) | VAF 27/118 reads (23%) | called by mutect2, pindel, varscan2
- RHAG | c.669del p.S224Afs*18 | Frame Shift Del (DEL) | VAF 24/52 reads (46%) | called by mutect2, pindel, varscan2
- SRSF10 | c.664A>T p.R222* | Nonsense Mutation (SNP) | VAF 57/254 reads (22%) | called by muse, mutect2, varscan2
- TLN2 | c.6945_6954del p.S2316Lfs*6 | Frame Shift Del (DEL) | VAF 21/35 reads (60%) | called by mutect2, pindel, varscan2
- TP53 | c.459dup p.G154Rfs*27 | Frame Shift Ins (INS) | VAF 37/74 reads (50%) | called by mutect2, pindel, varscan2
- VNN1 | c.1379del p.L460Cfs*4 | Frame Shift Del (DEL) | VAF 24/48 reads (50%) | called by mutect2, pindel, varscan2
- ABCG8 | c.261C>A p.G87= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99699934; called by muse, mutect2, varscan2
- ACTN2 | c.1287C>T p.Y429= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs764881077, COSV63977582; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ACTR10 | c.861C>G p.S287= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV99581212; called by muse, mutect2, varscan2
- ADGRG7 | c.1810C>A p.R604= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV99841158; called by muse, mutect2, varscan2
- ADGRL2 | c.2904A>T p.S968= (on ENST00000370717 / NM_001366005.1; = p.S955= on NM_012302.4) | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs1388350987, COSV99589662; called by muse, mutect2, varscan2
- AHNAK2 | c.9387G>T p.L3129= | Silent (SNP) | VAF 220/541 reads (41%) | catalogued as COSV100317901; called by muse, mutect2, varscan2
- ALOX12B | c.1584G>A p.E528= | Silent (SNP) | VAF 160/239 reads (67%) | catalogued as COSV100047300; called by muse, mutect2, varscan2
- ANK2 | c.10902T>G p.V3634= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV100002227; called by muse, mutect2, varscan2
- ARHGAP10 | c.172C>A p.R58= | Silent (SNP) | VAF 21/160 reads (13%) | catalogued as COSV100331345; called by muse, mutect2, varscan2
- ASB2 | c.843C>T p.D281= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs149110212; called by muse, mutect2, varscan2
- ATAD2B | c.2724A>G p.Q908= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99477881; called by muse, mutect2, varscan2
- BBX | c.588C>T p.N196= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as COSV100361773; called by muse, mutect2
- BICC1 | c.942A>T p.T314= | Silent (SNP) | VAF 50/95 reads (53%) | catalogued as COSV99570649; called by muse, mutect2, varscan2
- CAGE1 | c.1453T>C p.L485= (on ENST00000512086; = p.L349= on NM_205864.3) | Silent (SNP) | VAF 39/48 reads (81%) | catalogued as rs373407949, COSV99699806; called by muse, mutect2, varscan2
- CAMKK1 | c.1506G>A p.E502= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1451045259, COSV99340356; called by muse, mutect2, varscan2
- CBLN4 | c.318C>T p.F106= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as COSV99290598; called by muse, mutect2
- CCT2 | c.768A>C p.V256= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV100167693, COSV54740513; called by muse, mutect2, varscan2
- COL22A1 | c.2781C>A p.P927= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100278932, COSV57328404; called by muse, mutect2
- COL6A3 | c.3399C>G p.P1133= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99799110; called by mutect2, varscan2
- COLEC12 | c.2175C>A p.V725= | Silent (SNP) | VAF 131/206 reads (64%) | catalogued as COSV101232096; called by muse, mutect2, varscan2
- CREB1 | c.345G>T p.V115= (on ENST00000432329 / NM_134442.5; = p.V101= on NM_004379.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100783587; called by muse, mutect2
- CTIF | c.456T>C p.D152= | Silent (SNP) | VAF 42/61 reads (69%) | catalogued as COSV99837774; called by muse, mutect2, varscan2
- DGLUCY | c.198G>T p.L66= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as COSV99824390; called by muse, mutect2, varscan2
- DHRS9 | c.525C>T p.G175= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV100513553; called by muse, mutect2, varscan2
- DHX37 | c.189C>A p.P63= | Silent (SNP) | VAF 56/105 reads (53%) | catalogued as COSV100439301; called by muse, mutect2, varscan2
- DHX9 | c.3123C>T p.P1041= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100841230, COSV100841438; called by muse, mutect2, varscan2
- DIDO1 | c.6063G>A p.P2021= | Silent (SNP) | VAF 17/140 reads (12%) | catalogued as COSV99826201; called by muse, mutect2, varscan2
- DIPK2B | c.1080G>T p.L360= | Silent (SNP) | VAF 16/19 reads (84%) | catalogued as COSV101211682; called by muse, mutect2, varscan2
- DISP1 | c.3381C>T p.F1127= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV99451268; called by muse, mutect2, varscan2
- DPP4 | c.2175T>C p.D725= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV100858911; called by muse, mutect2, varscan2
- DUSP12 | c.711C>T p.H237= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV100909729; called by muse, mutect2, varscan2
- DYSF | c.5067G>C p.P1689= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV50454937, COSV99247944; called by muse, mutect2, varscan2
- EEPD1 | c.697C>T p.L233= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99632209; called by muse, mutect2, varscan2
- ESX1 | c.897C>A p.P299= | Silent (SNP) | VAF 11/11 reads (100%) | catalogued as COSV101006476; called by muse, mutect2, varscan2
- F2 | c.801G>T p.G267= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs752552095, COSV100319566, COSV61315291; called by muse, mutect2, varscan2
- FAM102A | c.195C>T p.F65= | Silent (SNP) | VAF 46/62 reads (74%) | catalogued as COSV100305563; called by muse, mutect2, varscan2
- FAM83G | c.1083C>T p.A361= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as COSV100525231; called by muse, mutect2, varscan2
- FAT3 | c.10551C>T p.Y3517= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs372288167; called by muse, mutect2, varscan2
- FGD3 | c.1500G>T p.T500= | Silent (SNP) | VAF 35/56 reads (63%) | catalogued as rs1432723006, COSV61596934, COSV61597917; called by muse, mutect2, varscan2
- FLI1 | c.843C>A p.I281= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV99857854; called by mutect2, varscan2
- GPR37 | c.1365G>A p.T455= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as COSV58257290; called by muse, mutect2, varscan2
- GPRASP2 | c.141G>T p.G47= | Silent (SNP) | VAF 29/40 reads (73%) | catalogued as COSV100176805; called by muse, mutect2, varscan2
- GPRIN1 | c.1542G>T p.A514= | Silent (SNP) | VAF 49/80 reads (61%) | catalogued as rs370201638, COSV56136925; called by muse, mutect2, varscan2
- GRIA4 | c.2664C>A p.I888= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1411262059, COSV99232329; called by muse, mutect2, varscan2
- GUCY1A1 | c.1407G>A p.G469= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as COSV99637942; called by muse, mutect2, varscan2
- HARBI1 | c.498G>A p.V166= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as COSV100365802, COSV56320778; called by muse, mutect2, varscan2
- HAVCR1 | c.867G>T p.T289= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs370862249, COSV100208369; called by muse, mutect2, varscan2
- HDAC4 | c.2181C>T p.P727= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV61860327; called by muse, mutect2, varscan2
- HNF4G | c.768A>C p.P256= (on ENST00000354370 / NM_001330561.2; = p.P303= on NM_004133.5) | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV100584632; called by muse, mutect2, varscan2
- HRH3 | c.1077G>A p.S359= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs775772906, COSV100420637; called by muse, mutect2
- IGHM | c.426G>T p.R142= | Silent (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- IGHV2-5 | c.87G>C p.T29= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs370553500; called by muse, mutect2, varscan2
- IL17RD | c.219T>C p.H73= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as rs1443523583, COSV99577415; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITPR2 | c.7008G>T p.G2336= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV101190037; called by muse, mutect2, varscan2
- KBTBD13 | c.60C>T p.A20= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs774808670, COSV101416695; called by muse, varscan2
- KCNB1 | c.2181C>G p.T727= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100870509; called by muse, mutect2, varscan2
- KCNJ8 | c.1266G>A p.S422= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs772569559, COSV99557612; ClinVar: likely benign; called by muse, mutect2, varscan2
- KHSRP | c.1233A>T p.R411= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV101231197; called by muse, mutect2
- KIR2DL3 | c.258C>T p.S86= | Silent (SNP) | VAF 99/386 reads (26%) | catalogued as rs1345543961; called by muse, mutect2, varscan2
- LIPN | c.24A>T p.T8= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV101356226; called by muse, mutect2
- MGAT4C | c.276C>A p.A92= | Silent (SNP) | VAF 49/106 reads (46%) | catalogued as COSV100153048; called by muse, mutect2, varscan2
- MOCS1 | c.148C>T p.L50= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs1001206381, COSV100418668; called by muse, mutect2, varscan2
- MORC4 | c.717A>G p.Q239= | Silent (SNP) | VAF 52/79 reads (66%) | catalogued as rs780310889, COSV99717319; called by muse, mutect2, varscan2
- MUC5B | c.11715C>A p.T3905= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV101500442; called by muse, mutect2, varscan2
- MUC6 | c.3897C>A p.P1299= | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as COSV101424642; called by muse, varscan2
- MUC7 | c.726T>A p.S242= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV100512332; called by muse, mutect2, varscan2
- MYO3B | c.384G>A p.L128= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs1256049574, COSV100510576; called by muse, mutect2, varscan2
- NAV3 | c.5640G>A p.Q1880= (on ENST00000397909 / NM_001024383.2; = p.Q1858= on NM_014903.6) | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV99892178; called by muse, mutect2, varscan2
- NBPF9 | c.114C>A p.L38= | Silent (SNP) | VAF 35/194 reads (18%) | called by muse, mutect2, varscan2
- NEDD1 | c.1791G>A p.Q597= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99901095; called by muse, mutect2, varscan2
- NFKBIZ | c.1158G>T p.V386= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV100397102; called by muse, mutect2, varscan2
- NPAP1 | c.537C>A p.P179= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100275571; called by muse, mutect2, varscan2
- NRAP | c.4794C>A p.S1598= (on ENST00000359988 / NM_001322945.2; = p.S1563= on NM_006175.4) | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100667969; called by muse, mutect2, varscan2
- OR2AT4 | c.837C>T p.G279= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100532260, COSV100532357; called by muse, mutect2
- OR2J3 | c.372C>T p.D124= | Silent (SNP) | VAF 119/180 reads (66%) | catalogued as rs757035122, COSV65849796; called by muse, mutect2, varscan2
- OR4K1 | c.726C>A p.A242= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as COSV99579085; called by muse, mutect2, varscan2
- OR52R1 | c.210C>A p.A70= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100617742; called by muse, varscan2
- OR56A3 | c.576C>A p.S192= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100289936, COSV100290251; called by muse, mutect2
- OR5H15 | c.244C>T p.L82= | Silent (SNP) | VAF 42/232 reads (18%) | catalogued as rs1249426238, COSV100736688; called by muse, varscan2
- OR8B12 | c.696C>A p.G232= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100172634, COSV100172807; called by muse, mutect2, varscan2
- OR9Q2 | c.207G>T p.V69= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV100285461; called by muse, mutect2, varscan2
- PALLD | c.2628C>T p.R876= (on ENST00000505667 / NM_001166108.2; = p.R859= on NM_016081.4) | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as COSV99825017; called by muse, mutect2, varscan2
- PARD3B | c.2626C>T p.L876= (on ENST00000406610 / NM_001302769.2; = p.L807= on NM_057177.7) | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100593891; called by mutect2, varscan2
- PCDH10 | c.1179G>T p.V393= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99993817; called by muse, mutect2, varscan2
- PCDHGB2 | c.2094G>A p.L698= | Silent (SNP) | VAF 80/117 reads (68%) | catalogued as rs900469098, COSV99540450; called by muse, mutect2, varscan2
- PLSCR1 | c.585C>T p.I195= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs866920436, COSV100678410; called by muse, mutect2, varscan2
- POLE | c.3651C>A p.L1217= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100267143, COSV57682928; called by mutect2, varscan2
- POTEE | c.2424C>G p.A808= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as rs1237268062, COSV100388195, COSV58244413; called by muse, mutect2, varscan2
- PRG2 | c.126A>G p.P42= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100314952; called by muse, mutect2, varscan2
- RESF1 | c.1182A>T p.V394= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100440403; called by muse, mutect2, varscan2
- RGS1 | c.552G>A p.K184= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs533948018, COSV100817505; called by muse, mutect2, varscan2
- ROBO4 | c.1326C>A p.A442= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100127652; called by muse, mutect2, varscan2
- RP1L1 | c.3264G>T p.A1088= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs781205150, COSV101223328; called by muse, mutect2, varscan2
- RYR2 | c.13011C>G p.P4337= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs556345275, COSV100771097; called by muse, mutect2, varscan2
- SERPINI1 | c.564G>T p.G188= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV99855139; called by muse, mutect2, varscan2
- SIX3 | c.204C>A p.G68= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99578432; called by muse, mutect2, varscan2
- SPTA1 | c.123G>T p.R41= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100935119; called by muse, mutect2, varscan2
- SPTBN2 | c.3024G>A p.L1008= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100019684; called by muse, mutect2, varscan2
- STAG3 | c.711G>A p.L237= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV100426001; called by muse, mutect2, varscan2
- SYNDIG1 | c.436C>T p.L146= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as COSV100965308; called by muse, mutect2, varscan2
- SYTL5 | c.741C>A p.T247= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs1273379385, COSV99937367; called by muse, mutect2, varscan2
- TCF20 | c.5058C>A p.S1686= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs1220852180, COSV100166678; called by muse, mutect2, varscan2
- TDRD6 | c.1794G>T p.V598= | Silent (SNP) | VAF 54/89 reads (61%) | catalogued as COSV60175375; called by muse, mutect2, varscan2
- TENM1 | c.2817C>T p.F939= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as rs746512976, COSV64430306; called by muse, mutect2, varscan2
- TGFBR2 | c.1290A>G p.L430= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99847408; called by muse, mutect2, varscan2
- TMEM130 | c.579G>T p.V193= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs1554398984, COSV100228834, COSV100229017; called by muse, mutect2, varscan2
- TNIK | c.1245G>T p.L415= | Silent (SNP) | VAF 82/149 reads (55%) | catalogued as COSV99457816; called by muse, mutect2, varscan2
- TRMT6 | c.885A>G p.K295= | Silent (SNP) | VAF 49/96 reads (51%) | catalogued as COSV99177581; called by muse, mutect2, varscan2
- TRPC5 | c.1554C>T p.L518= | Silent (SNP) | VAF 31/51 reads (61%) | catalogued as COSV53291108, COSV53299210, COSV99461393; called by muse, mutect2, varscan2
- TYK2 | c.2118G>T p.V706= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV99314322; called by muse, mutect2, varscan2
- ZNF181 | c.999G>T p.V333= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV101106308; called by muse, mutect2, varscan2
- ZNF707 | c.483G>T p.P161= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs782158906, COSV100690650; called by muse, mutect2, varscan2
- CORT | c.-14A>T | 5'UTR (SNP) | VAF 13/76 reads (17%) | catalogued as COSV100259222; called by muse, mutect2, varscan2
- CTSL3P | n.508G>C | RNA (SNP) | VAF 31/44 reads (70%) | called by muse, mutect2, varscan2
- CYP2C9 | c.*2G>A | 3'UTR (SNP) | VAF 27/64 reads (42%) | catalogued as rs774423253, COSV99582810; called by muse, mutect2, varscan2
- DCHS2 | n.3410G>T | RNA (SNP) | VAF 24/129 reads (19%) | catalogued as COSV100252181; called by muse, mutect2, varscan2
- FBXL21P | n.975-492A>G | Intron (SNP) | VAF 12/19 reads (63%) | catalogued as rs1416605157, COSV99778343; called by muse, mutect2, varscan2
- MDS2 | n.554C>A | RNA (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895973 C>T | 5'Flank (SNP) | VAF 9/25 reads (36%) | catalogued as rs779451437, COSV60002108; called by muse, mutect2, varscan2
- SSPOP | n.3887C>T | RNA (SNP) | VAF 24/57 reads (42%) | catalogued as rs1312906391, COSV100022637; called by muse, mutect2, varscan2
- VKORC1 | c.173+217C>G | Intron (SNP) | VAF 84/124 reads (68%) | catalogued as COSV100161780; called by muse, mutect2
- VKORC1 | c.173+215T>A | Intron (SNP) | VAF 82/122 reads (67%) | catalogued as COSV100161782; called by muse, mutect2
- VNN3 | c.*48G>T | 3'UTR (SNP) | VAF 28/45 reads (62%) | catalogued as COSV99258387; called by muse, mutect2, varscan2
